TARGET case TARGET-20-PATDDA — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/933a95b7-ad2b-4e0e-a8e9-99dd41977b86

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 17 years; Vital status: Alive.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; ICD-10 code: C92.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 17.8 years (6,496 days); Year of diagnosis: 2009; Days to last follow up: 964 days (2.6 years).
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 2; Timepoint category: End of Treatment Course.
   Treatment given: Protocol identifier: AAML0631.
   Treatment given: Reason treatment ended: Course of Therapy Completed; Course number: 1; Timepoint category: End of Treatment Course.
   Recorded as not given: Stem Cell Transplantation, NOS, first complete response.

Follow-up (1 entry)
- Days to follow up: 964 days (2.6 years); Event-free: no event (relapse, second malignancy or death) recorded through day 964; Year of follow up: 2012.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 15.4 ×10³/µL; Blast Count 80%; Bone Marrow blast count 91%.

Biospecimens (1 sample)
- Sample TARGET-20-PATDDA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_AML_ClinicalData_AAML1031_AAML0631_additionalCasesForSortedCellsAndCBExperiment_20230720.xlsx:
- First Event: Censored
- Overall Survival Time in Days: 964
- WBC at Diagnosis: 15.4
- Bone marrow leukemic blast percentage (%): 91
- Peripheral blasts (%): 80
- FAB Category: M3
- Primary Cytogenetic Code: PML-RARA
- ISCN: 46,XY[20]
- SCT in 1st CR: No
